Gene-level copy-number profile of tumor specimen MP2PRT-PARKGN-TMP1-A from MP2PRT case MP2PRT-PARKGN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.9 years (1,439 days).
Specimen MP2PRT-PARKGN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e85fa4b9-0f56-44fd-a7c1-c9e84b883002.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PARKGN-NB1-A (blood derived cancer - peripheral blood, post-treatment); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/7e11d812-27e4-47d7-8879-1af4d0228644

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 157; copy number 1: 2,867; copy number 2: 55,528; copy number 3: 334.

Homozygous deletions (total copy number 0; autosomes only): 157 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,192,500–89,192,752, 1 gene (within-gene range 0–1): IGKV3-25.
- chr2:89,213,423–89,245,596, 4 genes (within-gene range 0–1): IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:22,438,547–22,494,883, 27 genes (within-gene range 0–2): TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48, TRAJ47, TRAJ46, TRAJ45, TRAJ44.
- chr14:105,672,308–106,481,706, 116 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:106,531,141–106,538,344, 2 genes (within-gene range 0–1): IGHVIII-47-1, IGHV3-48.
- chr14:106,680,603–106,704,286, 7 genes: IGHV1-67, SLC20A1P1, IGHVII-67-1, IGHVIII-67-2, IGHVIII-67-3, IGHVIII-67-4, IGHV1-68.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 1,082. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
